Somatic mutation profile of tumor specimen TCGA-AN-A0FD-01A (aliquot TCGA-AN-A0FD-01A-11W-A050-09) from TCGA case TCGA-AN-A0FD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.2 years (26,007 days).
Specimen TCGA-AN-A0FD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba72ca40-e70d-4d30-93fc-ac988b041d52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FD-10A (Blood Derived Normal), aliquot TCGA-AN-A0FD-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dad20043-1260-474c-92e5-63419a4909af

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.12031C>T p.R4011W | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772310771, COSV71292500; called by muse, mutect2, varscan2
- ACE | c.1346G>A p.S449N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as COSV52011344; called by muse, mutect2, varscan2
- ADGRL3 | c.761C>T p.S254L (on ENST00000506720 / NM_001322402.2; = p.S186L on NM_015236.6) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs865866030, COSV101547322; called by muse, mutect2
- ADPRH | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV63695578; called by muse, mutect2, varscan2
- AFDN | c.4199C>T p.P1400L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs571941763, COSV60052019; called by muse, mutect2, varscan2
- ALDH1L2 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV51558542; called by muse, mutect2
- CEP290 | c.214del p.E72Kfs*2 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as CM131894, COSV57125531; called by pindel, varscan2
- CFH | c.1643C>G p.T548S | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.469); catalogued as COSV66411555; called by muse, mutect2, varscan2
- DBX2 | c.917G>C p.S306T | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs1171348289, COSV60339023; called by muse, mutect2, varscan2
- DCAF17 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64544603, COSV64545828; called by muse, mutect2, varscan2
- DOCK11 | c.4897G>T p.G1633* | Nonsense Mutation (SNP) | VAF 70/116 reads (60%) | catalogued as COSV52244856; called by muse, mutect2, varscan2
- GATA3 | c.1180dup p.A394Gfs*113 | Frame Shift Ins (INS) | VAF 29/129 reads (22%) | catalogued as COSV60520482; called by pindel, varscan2
- MAP4K1 | c.1724A>T p.E575V | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.478); catalogued as COSV67712149; called by muse, mutect2, varscan2
- PCDH18 | c.3041G>A p.R1014H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs199723290, COSV61270631; called by muse, mutect2, varscan2
- POGZ | c.3377A>G p.D1126G | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51852650, COSV51852716; called by muse, mutect2, varscan2
- RGS9 | c.1742C>G p.S581C | Missense Mutation (SNP) | VAF 93/172 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as COSV52227819, COSV52228013; called by muse, varscan2
- RWDD3 | c.481A>T p.K161* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV55722710; called by muse, mutect2, varscan2
- SMARCAL1 | c.1698G>T p.M566I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV61922794; called by muse, mutect2, varscan2
- TAS2R8 | c.851T>C p.I284T | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53690206; called by muse, mutect2, varscan2
- TBL1X | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54285804; called by muse, mutect2, varscan2
- TMEM214 | c.739T>G p.S247A | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV53193572; called by muse, mutect2, varscan2
- VDAC2 | c.653A>T p.N218I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV53687080; called by muse, mutect2, varscan2
- WAC | c.227_228del p.S76Kfs*11 | Frame Shift Del (DEL) | VAF 45/157 reads (29%) | catalogued as COSV61569006; called by mutect2, pindel, varscan2
- WDR17 | c.580A>C p.I194L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54580172; called by muse, mutect2, varscan2
- ZEB1 | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58051258; called by muse, mutect2, varscan2
- ZNF131 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV61003944; called by muse, mutect2, varscan2
- DGKE | c.1578C>A p.A526= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as COSV52350871; called by muse, mutect2, varscan2
- FAM111A | c.1188G>A p.E396= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV64655708; called by muse, mutect2, varscan2
- KMT2A | c.11868C>G p.P3956= | Silent (SNP) | VAF 60/75 reads (80%) | catalogued as COSV63290427; called by muse, mutect2, varscan2
- MRAP2 | c.498C>A p.I166= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as rs777763534, COSV57633937, COSV57634207; called by muse, mutect2, varscan2
- NXF1 | c.660C>T p.Y220= | Silent (SNP) | VAF 138/442 reads (31%) | catalogued as rs150232290; called by muse, mutect2, varscan2
- PTPN23 | c.1857C>T p.N619= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV55546864; called by muse, mutect2, varscan2
- SPRY1 | c.408A>G p.L136= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs368026966; called by muse, mutect2, varscan2
- VMP1 | c.552C>T p.I184= | Silent (SNP) | VAF 71/570 reads (12%) | catalogued as COSV51870644; called by muse, mutect2, varscan2
